Somatic mutation profile of tumor specimen MP2PRT-PATWDH-TMP1-A (aliquot MP2PRT-PATWDH-TMP1-A-1-0-D-A82L-36) from MP2PRT case MP2PRT-PATWDH, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.4 years (1,623 days).
Specimen MP2PRT-PATWDH-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3ce74c32-7711-42e2-b0d2-a9826434286d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATWDH-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATWDH-NB1-A-1-0-D-A82L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4511d8bc-d493-4734-ba7e-fb8887ba8db3

The open-access MAF lists 86 somatic variants for this specimen: 55 protein-altering or splice-affecting, 22 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 48, Silent 22, Intron 5, Nonsense Mutation 4, 5'Flank 3, Splice Region 1, RNA 1, Frame Shift Ins 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HPSE2 | c.1516C>T p.R506* | Nonsense Mutation (SNP) | VAF 196/403 reads (49%) | catalogued as rs267606866, CM103331, COSV65181961; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MTOR | c.6644C>T p.S2215F | Missense Mutation (SNP) | VAF 104/311 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as rs587777894, COSV63868278, COSV63868313; ClinVar: not provided / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SMARCA4 | c.2918G>A p.R973Q | Missense Mutation (SNP) | VAF 119/398 reads (30%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV60786475, COSV60810612; called by muse, mutect2, varscan2
- ANKRD34B | c.257C>T p.T86M | Missense Mutation (SNP) | VAF 208/433 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs747481528; called by mutect2, varscan2
- BRINP2 | c.1043C>T p.P348L | Missense Mutation (SNP) | VAF 121/341 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV64179598; called by muse, mutect2, varscan2
- C8orf34 | c.1021G>A p.D341N | Missense Mutation (SNP) | VAF 136/497 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV61377800, COSV61383736; called by muse, mutect2, varscan2
- CACNA2D1 | c.1313G>A p.G438E | Missense Mutation (SNP) | VAF 71/246 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.101); catalogued as COSV100667192, COSV62390165; called by muse, mutect2, varscan2
- CDH7 | c.1441G>A p.E481K | Missense Mutation (SNP) | VAF 81/331 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.078); catalogued as COSV100542597; called by muse, mutect2, varscan2
- CFAP61 | c.1864C>T p.R622* | Nonsense Mutation (SNP) | VAF 133/344 reads (39%) | catalogued as rs147638085, COSV55640870; called by muse, mutect2, varscan2
- COL14A1 | c.5039C>T p.P1680L | Missense Mutation (SNP) | VAF 216/414 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs750584569; called by muse, mutect2, varscan2
- DMD | c.8609G>A p.R2870Q | Missense Mutation (SNP) | VAF 88/244 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.345); catalogued as rs373481995, COSV100629636, COSV58915629; called by muse, mutect2, varscan2
- DNAH6 | c.3901G>A p.A1301T | Missense Mutation (SNP) | VAF 52/315 reads (17%) | SIFT tolerated (0.48); PolyPhen benign (0.039); catalogued as rs148175693, COSV99406582; called by muse, mutect2, varscan2
- FAT3 | c.1819G>A p.E607K | Missense Mutation (SNP) | VAF 107/271 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1409407461, COSV53095428; called by muse, mutect2, varscan2
- FRMPD1 | c.2246C>T p.S749F | Missense Mutation (SNP) | VAF 170/488 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.496); catalogued as rs746052003; called by muse, mutect2, varscan2
- GALNT2 | c.628C>T p.R210W | Missense Mutation (SNP) | VAF 108/303 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs139591495; called by muse, mutect2, varscan2
- MUC12 | c.10184C>T p.S3395L (on ENST00000379442; = p.S3252L on NM_001164462.1) | Missense Mutation (SNP) | VAF 222/4779 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.316); catalogued as rs756938077, COSV65207769; called by muse, mutect2
- MUC16 | c.4214C>T p.S1405L | Missense Mutation (SNP) | VAF 127/355 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.048); catalogued as COSV67453469; called by muse, mutect2, varscan2
- NME6 | c.361C>T p.L121F (on ENST00000415053; = p.L129F on NM_005793.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 144/379 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as rs1244117845; called by muse, mutect2, varscan2
- NUAK1 | c.1372C>A p.Q458K | Missense Mutation (SNP) | VAF 107/406 reads (26%) | SIFT tolerated (0.83); PolyPhen benign (0.09); catalogued as rs373657293; called by muse, mutect2, varscan2
- OR8K5 | c.278C>T p.S93F | Missense Mutation (SNP) | VAF 108/323 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.914); catalogued as COSV57889769; called by muse, mutect2, varscan2
- POC1B | c.442C>T p.R148C | Missense Mutation (SNP) | VAF 54/205 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.096); catalogued as rs759962945, COSV57968056; called by muse, mutect2, varscan2
- POU5F1 | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 141/557 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.129); catalogued as COSV99463087; called by muse, mutect2, varscan2
- PSD3 | c.181C>T p.P61S | Missense Mutation (SNP) | VAF 101/410 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.449); catalogued as rs747194534; called by muse, mutect2, varscan2
- RASGRF2 | c.2630C>T p.S877L | Missense Mutation (SNP) | VAF 131/500 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV54125068; called by muse, mutect2, varscan2
- SEZ6L2 | c.244C>T p.P82S | Missense Mutation (SNP) | VAF 161/471 reads (34%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV58103005; called by muse, mutect2
- SNX11 | c.172delinsGG p.R58Gfs*5 | Frame Shift Ins (INS) | VAF 102/462 reads (22%) | catalogued as COSV100821773; called by pindel, varscan2*
- SPAG5 | c.2879C>T p.P960L | Missense Mutation (SNP) | VAF 82/405 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.813); catalogued as rs1176640119; called by muse, mutect2, varscan2
- TMEM132A | c.1097C>T p.P366L (on ENST00000453848 / NM_178031.3; = p.P367L on NM_017870.4) | Missense Mutation (SNP) | VAF 160/442 reads (36%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.93); catalogued as COSV50002194; called by muse, mutect2, varscan2
- WDR64 | c.1154C>T p.S385F | Missense Mutation (SNP) | VAF 101/290 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs766877773, COSV100844070, COSV63801182; called by muse, mutect2, varscan2
- ZDHHC11B | c.1013C>T p.S338L | Missense Mutation (SNP) | VAF 89/382 reads (23%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0); catalogued as rs745750361; called by muse, mutect2, varscan2
- AJAP1 | c.721G>A p.D241N | Missense Mutation (SNP) | VAF 171/542 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0.087); called by muse, varscan2
- ANK3 | c.8792G>A p.R2931K | Missense Mutation (SNP) | VAF 188/376 reads (50%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- ANKRD30B | c.1672G>A p.A558T | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- BBS9 | c.1312C>T p.P438S | Missense Mutation (SNP) | VAF 73/236 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.746); called by muse, mutect2, varscan2
- BDNF | c.499C>T p.L167F | Missense Mutation (SNP) | VAF 170/432 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- C1orf87 | c.1193G>A p.G398E | Missense Mutation (SNP) | VAF 57/186 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.147); called by muse, mutect2
- CFHR3 | c.201G>A p.W67* | Nonsense Mutation (SNP) | VAF 86/292 reads (29%) | called by muse, mutect2, varscan2
- CUBN | c.8891C>T p.S2964F | Missense Mutation (SNP) | VAF 62/234 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.431); called by muse, mutect2, varscan2
- DUSP8 | c.998C>A p.P333Q | Missense Mutation (SNP) | VAF 281/718 reads (39%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.558); called by muse, mutect2, varscan2
- EPB42 | c.1368G>A p.M456I (on ENST00000441366 / NM_001114134.2; = p.M486I on NM_000119.3) | Missense Mutation (SNP) | VAF 116/316 reads (37%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAF1 | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 76/235 reads (32%) | SIFT tolerated (0.67); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- FYB1 | c.1970C>T p.S657F (on ENST00000351578 / NM_199335.5; = p.S703F on NM_001465.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 56/278 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- GALNTL6 | c.738C>T p.L246= | Splice Region (SNP) | VAF 105/287 reads (37%) | called by muse, mutect2, varscan2
- ITGB2 | c.479_480insGGG p.I160delinsMG | In Frame Ins (INS) | VAF 74/460 reads (16%) | called by mutect2, pindel, varscan2
- ITGB8 | c.524G>A p.R175K | Missense Mutation (SNP) | VAF 64/191 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- KREMEN1 | c.1462C>T p.Q488* | Nonsense Mutation (SNP) | VAF 114/345 reads (33%) | called by muse, mutect2, varscan2
- MFSD13A | c.502C>T p.L168F | Missense Mutation (SNP) | VAF 215/805 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.166); called by muse, mutect2, varscan2
- MUC17 | c.11981C>T p.P3994L | Missense Mutation (SNP) | VAF 164/430 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC25A40 | c.934C>T p.P312S | Missense Mutation (SNP) | VAF 73/207 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SPINDOC | c.535C>T p.L179F | Missense Mutation (SNP) | VAF 178/486 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- STAB2 | c.6755G>A p.G2252E | Missense Mutation (SNP) | VAF 123/399 reads (31%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- SV2A | c.1913C>T p.S638F | Missense Mutation (SNP) | VAF 107/301 reads (36%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.596); called by muse, mutect2, varscan2
- SYTL2 | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 92/278 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.577); called by muse, mutect2, varscan2
- XIRP2 | c.9479G>A p.R3160K (on ENST00000628543; = p.R3335K on NM_152381.6) | Missense Mutation (SNP) | VAF 95/277 reads (34%) | SIFT tolerated (0.44); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF565 | c.224C>T p.T75I (on ENST00000355114; = p.T35I on NM_152477.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 122/357 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.746); called by muse, mutect2, varscan2
- ACSF3 | c.1080C>T p.I360= | Silent (SNP) | VAF 146/411 reads (36%) | catalogued as rs749101905; called by muse, mutect2, varscan2
- ATP10B | c.1860G>A p.K620= | Silent (SNP) | VAF 95/325 reads (29%) | called by muse, mutect2, varscan2
- BBS9 | c.1311C>T p.V437= | Silent (SNP) | VAF 73/236 reads (31%) | catalogued as rs1400092534, COSV54179620; called by muse, mutect2, varscan2
- C19orf85 | c.501C>T p.D167= | Silent (SNP) | VAF 189/609 reads (31%) | called by muse, mutect2, varscan2
- CDH20 | c.315C>T p.I105= | Silent (SNP) | VAF 132/452 reads (29%) | catalogued as rs1382656822, COSV53008079, COSV53016468; called by muse, mutect2
- CHAMP1 | c.1449C>T p.S483= | Silent (SNP) | VAF 147/396 reads (37%) | catalogued as rs1555379770; called by muse, mutect2, varscan2
- CNDP1 | c.1380C>T p.I460= | Silent (SNP) | VAF 128/536 reads (24%) | catalogued as rs774635198, COSV62593188, COSV62595636; called by muse, mutect2, varscan2
- CUBN | c.8892C>T p.S2964= | Silent (SNP) | VAF 59/229 reads (26%) | called by muse, mutect2, varscan2
- DST | c.10461T>A p.S3487= | Silent (SNP) | VAF 105/442 reads (24%) | called by muse, mutect2, varscan2
- FAM47E | c.954C>T p.D318= | Silent (SNP) | VAF 134/431 reads (31%) | catalogued as rs759825030, COSV60532040; called by muse, mutect2, varscan2
- KCNH4 | c.2109C>T p.S703= | Silent (SNP) | VAF 139/568 reads (24%) | called by muse, mutect2, varscan2
- MANBA | c.2706C>T p.Y902= (on ENST00000642252; = p.Y856= on NM_005908.4) | Silent (SNP) | VAF 108/323 reads (33%) | catalogued as rs1451916324, COSV56972028; called by muse, mutect2, varscan2
- NPY2R | c.939C>T p.I313= | Silent (SNP) | VAF 125/390 reads (32%) | catalogued as rs762985604, COSV61528638; called by muse, mutect2, varscan2
- OR13C4 | c.939G>A p.R313= | Silent (SNP) | VAF 45/125 reads (36%) | called by muse, mutect2, varscan2
- OR5D16 | c.783C>T p.Y261= | Silent (SNP) | VAF 159/431 reads (37%) | called by muse, mutect2, varscan2
- PCDHA10 | c.1446C>T p.D482= | Silent (SNP) | VAF 226/916 reads (25%) | catalogued as COSV56541619; called by muse, mutect2, varscan2
- PCDHA11 | c.1437G>A p.R479= | Silent (SNP) | VAF 232/887 reads (26%) | catalogued as rs1554164388, COSV56489427; called by muse, mutect2, varscan2
- PCDHA8 | c.1410G>A p.P470= | Silent (SNP) | VAF 253/976 reads (26%) | catalogued as rs202126810, COSV65334668, COSV65339563; called by muse, mutect2, varscan2
- PDZRN4 | c.36G>A p.V12= | Silent (SNP) | VAF 146/456 reads (32%) | catalogued as rs1367219980; called by muse, mutect2, varscan2
- SERPINB12 | c.897C>T p.F299= | Silent (SNP) | VAF 148/545 reads (27%) | catalogued as COSV54034467; called by muse, mutect2, varscan2
- SLC17A6 | c.123C>T p.I41= | Silent (SNP) | VAF 144/394 reads (37%) | called by muse, mutect2, varscan2
- SUSD4 | c.381C>T p.I127= | Silent (SNP) | VAF 72/239 reads (30%) | catalogued as rs776519802, COSV59553299; called by muse, mutect2, varscan2
- AC233702.8 | chr17:21551104 G>A | 5'Flank (SNP) | VAF 122/566 reads (22%) | called by muse, mutect2, varscan2
- AC233702.8 | chr17:21551105 G>A | 5'Flank (SNP) | VAF 123/564 reads (22%) | catalogued as rs201484956; called by muse, mutect2, varscan2
- ADGRA1 | c.4-1263G>A | Intron (SNP) | VAF 141/549 reads (26%) | catalogued as COSV101192824; called by muse, mutect2, varscan2
- MLIP | c.613-11692C>T | Intron (SNP) | VAF 190/687 reads (28%) | called by muse, mutect2, varscan2
- NPAP1L | n.841C>T | RNA (SNP) | VAF 92/279 reads (33%) | called by muse, mutect2, varscan2
- SELENBP1 | c.5-63G>A | Intron (SNP) | VAF 198/597 reads (33%) | catalogued as rs766284008, COSV64373310; called by muse, mutect2, varscan2
- TLX3 | chr5:171308471 G>A | 5'Flank (SNP) | VAF 266/1048 reads (25%) | called by muse, mutect2, varscan2
- VIT | c.487+75G>A | Intron (SNP) | VAF 85/237 reads (36%) | catalogued as rs1422470748, COSV101007447; called by muse, mutect2, varscan2
- VSTM2A | c.634+3808C>T | Intron (SNP) | VAF 134/458 reads (29%) | catalogued as rs903409682, COSV100172866; called by muse, mutect2
